Somatic mutation profile of tumor specimen MP2PRT-PAVWXR-TMP1-A (aliquot MP2PRT-PAVWXR-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVWXR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,565 days).
Specimen MP2PRT-PAVWXR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df84bd50-6224-48b4-ab5f-d116c15adc64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWXR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWXR-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78e7c363-16cb-4cb8-ad61-43a0ec1494c4

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 144/292 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314586868, COSV54445348; called by muse, mutect2
- ERICH4 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as rs782756940, COSV55729358; called by muse, mutect2, varscan2
- FAM186B | c.247dup p.I83Nfs*17 | Frame Shift Ins (INS) | VAF 89/240 reads (37%) | catalogued as rs767474109; called by mutect2, pindel, varscan2
- ARHGAP21 | c.2642C>T p.S881L | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMP4 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 167/349 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- HAP1 | c.586A>G p.M196V | Missense Mutation (SNP) | VAF 122/250 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGEA12 | c.727A>G p.R243G | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.42); called by muse, mutect2
- PBX1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- RNF19B | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 281/559 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- FHAD1 | c.480G>A p.P160= | Silent (SNP) | VAF 175/405 reads (43%) | catalogued as rs747573827; called by muse, mutect2, varscan2
- PKHD1L1 | c.4290G>A p.P1430= | Silent (SNP) | VAF 109/267 reads (41%) | catalogued as rs776923220, COSV65741077; called by muse, mutect2, varscan2
- PLEKHB1 | c.444C>A p.V148= | Silent (SNP) | VAF 133/321 reads (41%) | called by muse, mutect2, varscan2
- TF | c.210C>T p.A70= | Silent (SNP) | VAF 96/211 reads (45%) | catalogued as rs780598076; called by muse, mutect2, varscan2
- WWP2 | c.2361C>T p.D787= | Silent (SNP) | VAF 83/195 reads (43%) | catalogued as rs1464455995; called by muse, mutect2, varscan2
